CCDI case PBCMKE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/c89e6b11-e6e1-4904-a9f7-262a08c78f9a

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Optic nerve; Age at diagnosis: 11.8 years (4,296 days).

Biospecimens (3 samples)
- Sample 0DVBRB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVBRE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVBRK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
